Gene-level copy-number profile of tumor specimen C3L-05239-05 from CPTAC case C3L-05239, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.3 years (14,364 days).
Specimen C3L-05239-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2b1743cf-843a-45d8-a70b-fc2c0875f7a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05239-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/eb643984-1d0f-4e43-bfad-a97edb651a01

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 9,506; copy number 2: 42,734; copy number 3: 4,642; copy number 4: 1,965; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,384,255–23,956,444, 44 genes: IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.
- chr9:61,615,835–61,642,494, 2 genes: FAM242D, Y_RNA.
- chr10:53,291,072–55,627,942, 5 genes (within-gene range 0–1): AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P.
- chr10:54,864,674–57,513,425, 11 genes: AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC025039.1, MIR3924, AL731534.1.
- chr15:21,293,653–21,307,855, 2 genes: AC068446.1, RNU6-1235P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,566,679–42,569,353, 2 genes, copy number 13: BX088651.4, BX088651.1.

Autosomal genes at a single copy (total copy number 1): 6,650. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
